Somatic mutation profile of tumor specimen TCGA-D1-A174-01A (aliquot TCGA-D1-A174-01A-11D-A12J-09) from TCGA case TCGA-D1-A174, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 51.2 years (18,702 days).
Specimen TCGA-D1-A174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8690abb9-c7c4-49cf-9662-d5f72d47dc1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A174-10A (Blood Derived Normal), aliquot TCGA-D1-A174-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fcdd604-b740-4661-9b74-c8a5529c5cf1

The open-access MAF lists 950 somatic variants for this specimen: 739 protein-altering or splice-affecting, 194 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 481, Silent 194, Frame Shift Del 176, Frame Shift Ins 32, Nonsense Mutation 30, Intron 9, Splice Site 8, In Frame Del 5, 3'Flank 3, Splice Region 3, Translation Start Site 2, RNA 2.

Variants (750 of 950; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DLL3 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as rs200275281, COSV52693230, COSV52694197; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 35/112 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1413del p.K471Nfs*11 | Frame Shift Del (DEL) | VAF 47/176 reads (27%) | catalogued as rs1553365719; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 74/219 reads (34%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 32/137 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.629del p.T210Ifs*11 | Frame Shift Del (DEL) | VAF 82/156 reads (53%) | catalogued as rs1060500114, COSV64289110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AARS1 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs369797061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV62321201; called by muse, mutect2, varscan2
- ABCG1 | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV59200493; called by muse, mutect2, varscan2
- ABI3 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs769714351, COSV56799151; called by muse, mutect2, varscan2
- ABI3BP | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 63/211 reads (30%) | catalogued as rs750938732, COSV52527991; called by muse, mutect2, varscan2
- AC126283.2 | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67097823; called by muse, mutect2
- ACAD10 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs759706100, COSV58153830; called by muse, mutect2, varscan2
- ACTN3 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as rs1192812672, COSV72207528; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 85/246 reads (35%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 50/195 reads (26%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 54/154 reads (35%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAM11 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52344302; called by muse, mutect2, varscan2
- ADAM22 | c.1720A>G p.N574D | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55969402; called by muse, mutect2
- ADGRB2 | c.4490G>A p.R1497H (on ENST00000373658 / NM_001364857.2; = p.R1496H on NM_001294335.2) | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs779141200, COSV57070471; called by muse, varscan2
- ADGRL1 | c.3293G>A p.C1098Y (on ENST00000340736 / NM_001008701.3; = p.C1093Y on NM_014921.5) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61563544; called by muse, mutect2, varscan2
- ADGRL2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041419067, COSV54651627; called by muse, mutect2, varscan2
- ADGRL2 | c.3643G>A p.A1215T (on ENST00000370717 / NM_001366005.1; = p.A1159T on NM_012302.4) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV54651646; called by muse, mutect2, varscan2
- AFF3 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV57839943; called by muse, mutect2, varscan2
- ALDH16A1 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53192551; called by muse, mutect2, varscan2
- AMPD2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs749468757, COSV56646171; called by muse, mutect2, varscan2
- AMY2B | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 326/1016 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs767077768, COSV63713965; called by muse, mutect2, varscan2
- ANK3 | c.12563A>G p.D4188G (on ENST00000280772 / NM_001320874.2; = p.D709G on NM_001149.3) | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV55043675; called by muse, varscan2
- ANKMY2 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV61010948; called by muse, mutect2
- ANKRD17 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1406817744, COSV58215307; called by muse, mutect2, varscan2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | catalogued as rs753570186; called by mutect2, varscan2
- ANPEP | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55589121, COSV55593873; called by muse, mutect2, varscan2
- AP1G1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 53/167 reads (32%) | catalogued as COSV55485331; called by muse, mutect2, varscan2
- AP3D1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61424442; called by muse, mutect2, varscan2
- AP4B1 | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV56723210; called by muse, mutect2, varscan2
- APP | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199549173, COSV60993533; called by muse, mutect2, varscan2
- AQR | c.3416C>T p.A1139V | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50029535, COSV50037098; called by muse, mutect2, varscan2
- ARAP3 | c.1580G>A p.C527Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53348542; called by muse, mutect2, varscan2
- ARAP3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV53348557; called by muse, mutect2, varscan2
- ARFGEF3 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1051206818, COSV52449979; called by muse, mutect2, varscan2
- ARFGEF3 | c.4937C>T p.A1646V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs768364928, COSV52449982; called by muse, mutect2, varscan2
- ARHGAP11B | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70288282; called by muse, mutect2, varscan2
- ARHGAP36 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52263732, COSV99357592; called by muse, mutect2
- ARHGEF17 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV55229284; called by muse, mutect2, varscan2
- ARHGEF28 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs371272526; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as COSV61388445; called by pindel, varscan2
- ARL8B | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 17/340 reads (5%) | catalogued as COSV56577041; called by muse, mutect2
- ARRDC3 | c.508del p.L170Cfs*24 | Frame Shift Del (DEL) | VAF 43/161 reads (27%) | catalogued as COSV54364441; called by mutect2, pindel, varscan2
- ASB6 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV52964361; called by muse, mutect2, varscan2
- ASPRV1 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57227367; called by muse, mutect2, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 97/370 reads (26%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ATAD2B | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs376297258, COSV53195015; called by muse, mutect2, varscan2
- ATF7IP2 | c.1718C>G p.T573R | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61092168; called by muse, mutect2, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as COSV52486004; called by mutect2, pindel, varscan2
- ATP11C | c.3296G>T p.R1099M | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV59559535; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATP2B2 | c.38del p.N13Tfs*94 | Frame Shift Del (DEL) | VAF 56/187 reads (30%) | catalogued as COSV59494570; called by mutect2, pindel, varscan2
- ATP7B | c.4082C>T p.A1361V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV54435072; called by muse, mutect2, varscan2
- ATR | c.4940G>A p.R1647H | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs758322712, COSV63383741; called by muse, mutect2, varscan2
- ATXN2L | c.2591A>G p.H864R | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV57365076; called by muse, mutect2, varscan2
- AZGP1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs199572012, COSV52796974; called by muse, mutect2, varscan2
- B3GNT7 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs375567551, COSV55005744; called by muse, mutect2
- BAG6 | c.3383G>A p.R1128Q (on ENST00000676571; = p.R1081Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1169045521, COSV52987874; called by muse, mutect2, varscan2
- BCAN | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61255385; called by muse, mutect2, varscan2
- BCKDHB | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV57509206; called by muse, mutect2
- BCL6B | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs754062790, COSV53426184; called by muse, mutect2, varscan2
- BCL7C | c.617dup p.L207Tfs*10 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs754078059; called by mutect2, varscan2
- BMPR2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); catalogued as rs397514497, CM085278, COSV65807497; called by muse, mutect2, varscan2
- BOD1L1 | c.2381G>T p.R794M | Missense Mutation (SNP) | VAF 25/674 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV50006486; called by muse, mutect2
- BPTF | c.8981C>T p.A2994V | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58831172; called by muse, mutect2, varscan2
- BRAP | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV58153818; called by muse, mutect2, varscan2
- BRINP1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as COSV56291785, COSV99776266; called by muse, mutect2, varscan2
- BRSK1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58664546, COSV58665929; called by muse, mutect2, varscan2
- BTBD7 | c.173dup p.R59Efs*14 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | catalogued as rs752512017; called by mutect2, varscan2
- C11orf16 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs762937171, COSV58166398; called by muse, mutect2, varscan2
- C12orf54 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1377406909, COSV58359909; called by muse, mutect2
- C1orf127 | c.2359del p.A787Pfs*7 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs1283160262; called by mutect2, varscan2
- C20orf194 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs779904443, COSV52691248; called by muse, varscan2
- C3orf56 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as COSV67755984; called by muse, mutect2, varscan2
- C4orf33 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55415322; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 92/294 reads (31%) | catalogued as rs372345940; called by mutect2, varscan2
- C9orf152 | c.625A>G p.R209G | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV68762661; called by muse, mutect2
- CA10 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as rs144171943; called by muse, mutect2
- CACNA1G | c.4430T>C p.M1477T | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61720118; called by muse, mutect2, varscan2
- CAMK1 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs755492997, COSV56537615; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs745547658; called by mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARMIL2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs757497724, COSV58022930; called by muse, mutect2, varscan2
- CASKIN1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); catalogued as rs766816604, COSV58869842; called by muse, mutect2, varscan2
- CASR | c.1804C>A p.L602M (on ENST00000490131; = p.L679M on NM_000388.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV56134125; called by muse, mutect2, varscan2
- CCDC121 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV53112595; called by muse, mutect2, varscan2
- CCDC158 | c.3129del p.K1043Nfs*17 | Frame Shift Del (DEL) | VAF 66/239 reads (28%) | catalogued as COSV101187150; called by mutect2, pindel, varscan2
- CCNB3 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs372451442, COSV52069879, COSV52074441; called by muse, mutect2
- CCND1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119102, COSV57119569, COSV57120578; called by muse, mutect2
- CCT2 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV54739086; called by muse, mutect2, varscan2
- CD70 | c.233del p.G78Afs*33 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as COSV99835502; called by mutect2, pindel, varscan2
- CDC25C | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149379419, COSV60398220; called by muse, mutect2, varscan2
- CDH26 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54842521; called by muse, mutect2, varscan2
- CDK5 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs905557030, COSV52520441; called by muse, mutect2, varscan2
- CDK5 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377383594; called by muse, mutect2, varscan2
- CDK5RAP3 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV58114212; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199844610, COSV58114220; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 69/223 reads (31%) | catalogued as rs753353408; called by mutect2, varscan2
- CELF1 | c.869C>T p.P290L (on ENST00000358597 / NM_001376422.1; = p.P286L on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV60109870, COSV60109952; called by muse, mutect2, varscan2
- CELSR1 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs1329500090, COSV53083312; called by muse, mutect2, varscan2
- CEP170B | c.749C>T p.T250M (on ENST00000453495; = p.T179M on NM_015005.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771227643, COSV69023169; called by muse, mutect2, varscan2
- CEP290 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 67/517 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV58348492; called by muse, mutect2, varscan2
- CFAP70 | c.591A>T p.Q197H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV60280848; called by muse, mutect2, varscan2
- CFAP97 | c.481del p.S161Afs*2 | Frame Shift Del (DEL) | VAF 77/257 reads (30%) | catalogued as rs34798240; called by mutect2, pindel, varscan2
- CFC1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as rs1467160550, COSV52090269, COSV99383512; called by muse, mutect2, varscan2
- CHD3 | c.4214del p.G1405Afs*20 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV57874907; called by mutect2, pindel, varscan2
- CHRM4 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs200850651, COSV63125958; called by muse, mutect2, varscan2
- CHRNA7 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs754418919, COSV60967589; called by mutect2, varscan2
- CHST11 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759962153, COSV57983610; called by muse, mutect2, varscan2
- CIAPIN1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs751344858, COSV67953193; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLIP2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56274154; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CNGA2 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 66/201 reads (33%) | catalogued as rs778881389, COSV61703116; called by muse, mutect2, varscan2
- CNTNAP1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as COSV52847826; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 52/80 reads (65%) | catalogued as rs374805044; called by mutect2, varscan2
- COL1A2 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV51952726; called by muse, mutect2, varscan2
- COL23A1 | c.359dup p.G121Rfs*116 | Frame Shift Ins (INS) | VAF 17/65 reads (26%) | catalogued as rs755950142; called by pindel, varscan2
- COL28A1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs372070313; called by muse, mutect2, varscan2
- COL4A2 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs745382040, COSV64624733; called by muse, mutect2
- COQ10A | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57523872, COSV57526065; called by muse, mutect2, varscan2
- CPNE3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52203927; called by muse, mutect2, varscan2
- CRACD | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV51714960; called by mutect2, varscan2
- CRACR2B | c.165+2T>C p.X55_splice | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as COSV58989076; called by muse, mutect2, varscan2
- CRYBG2 | c.3818_3819insT p.E1273Dfs*55 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | catalogued as COSV100366800, COSV57486127; called by mutect2, pindel, varscan2
- CSMD2 | c.7818G>A p.W2606* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as COSV53877657; called by muse, mutect2, varscan2
- CSTF3 | c.539T>C p.M180T | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV60609423; called by muse, mutect2, varscan2
- CTNNA1 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1297469358, COSV57069373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.2978del p.K993Rfs*12 | Frame Shift Del (DEL) | VAF 94/346 reads (27%) | catalogued as COSV99057763; called by mutect2, pindel, varscan2
- CTSE | c.68+2T>C p.X23_splice | Splice Site (SNP) | VAF 44/141 reads (31%) | catalogued as COSV63059693; called by muse, mutect2, varscan2
- CTSL | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs751087214, COSV58245654, COSV58246399; called by muse, mutect2, varscan2
- CUL9 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs532403631, COSV52725124; called by muse, mutect2, varscan2
- CUX1 | c.439C>T p.R147* (on ENST00000292535 / NM_181552.4; = p.R158* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 70/198 reads (35%) | catalogued as rs782297523, COSV52890867; called by muse, varscan2
- CYTH1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as rs746860002, COSV63118356; called by muse, mutect2, varscan2
- DDX19B | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1277563049, COSV55362575; called by muse, mutect2, varscan2
- DENND3 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs765959967, COSV52800780; called by muse, mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 150/485 reads (31%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DENND6B | c.1357dup p.Q453Pfs*9 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs772127145; called by mutect2, varscan2
- DHX32 | c.1867G>A p.G623S | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189315557, COSV52938098, COSV52943042; called by muse, mutect2, varscan2
- DISP2 | c.2744C>A p.P915Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.496); catalogued as COSV51116419, COSV99140517; called by muse, mutect2, varscan2
- DLL4 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV51060890; called by muse, mutect2, varscan2
- DMWD | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV52175434; called by muse, mutect2, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAJB2 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs370819068; called by muse, mutect2, varscan2
- DNAJC11 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778516519, COSV53784047; called by muse, mutect2, varscan2
- DNHD1 | c.13766C>T p.P4589L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54430345; called by muse, mutect2, varscan2
- DOCK1 | c.4217C>T p.T1406I | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV54729506; called by muse, mutect2, varscan2
- DOCK2 | c.3902G>A p.C1301Y | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV56941142; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 15/172 reads (9%) | catalogued as rs782552436; called by mutect2, pindel
- DOP1A | c.6364C>T p.Q2122* | Nonsense Mutation (SNP) | VAF 27/571 reads (5%) | catalogued as COSV52706711; called by muse, mutect2
- DSC3 | c.2546T>C p.V849A | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV64571667; called by muse, mutect2
- DSCAM | c.5131G>A p.V1711M | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV68020589; called by muse, mutect2, varscan2
- DSE | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs757929433, COSV59061763; called by muse, mutect2, varscan2
- DSP | c.3901C>T p.Q1301* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs1449629687, CM108957, COSV65791034; called by muse, mutect2, varscan2
- DUOX1 | c.3241G>A p.V1081M | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs149942815; called by muse, mutect2, varscan2
- DUOXA1 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50993030; called by muse, mutect2, varscan2
- DUS1L | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs768075209, COSV57647642; called by mutect2, varscan2
- DYRK3 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs567048952, COSV65605348; called by muse, mutect2, varscan2
- DZANK1 | c.650C>T p.P217L (on ENST00000262547 / NM_001099407.1; = p.P18L on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs757404761, COSV52747285; called by muse, mutect2, varscan2
- DZIP1L | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59519139; called by muse, mutect2, varscan2
- EDN2 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65423333; called by muse, mutect2, varscan2
- EDRF1 | c.1184C>A p.S395Y (on ENST00000356792 / NM_001202438.2; = p.S361Y on NM_015608.2) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61762359; called by muse, mutect2, varscan2
- EEF1A1 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV58548601; called by muse, mutect2, varscan2
- EEF1G | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV57743706; called by muse, mutect2, varscan2
- EEF2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58578527; called by muse, mutect2, varscan2
- EFCAB7 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | catalogued as rs769084440, COSV52130177, COSV52135163; called by muse, mutect2, varscan2
- EFL1 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1239093536, COSV51602656, COSV99187964; called by muse, mutect2
- EGFR | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587778250, COSV51769863; ClinVar: not provided; called by muse, mutect2, varscan2
- EIF2S3 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV53405748; called by muse, mutect2, varscan2
- ELANE | c.67+1del | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs886039350; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ELAPOR2 | c.2081G>A p.S694N (on ENST00000450689 / NM_001142749.3; = p.S527N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51883899; called by muse, mutect2, varscan2
- EML2 | c.819del p.N274Tfs*120 | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | catalogued as rs1568457333; called by mutect2, pindel, varscan2
- EPB41L2 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs748999213, COSV61353035; called by muse, mutect2, varscan2
- EPB41L4B | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs370630484; called by muse, mutect2, varscan2
- EPHA3 | c.1256G>C p.S419T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV60693711, COSV60728342; called by muse, mutect2, varscan2
- ERAP2 | c.2075G>C p.S692T | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV65938628; called by muse, mutect2, varscan2
- ERBIN | c.3830del p.P1277Lfs*14 (on ENST00000284037 / NM_001253697.2; = p.P1236Lfs*14 on NM_018695.4) | Frame Shift Del (DEL) | VAF 45/145 reads (31%) | catalogued as rs781559768; called by mutect2, pindel, varscan2
- ERCC1 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs534169621, COSV50003644; called by muse, mutect2
- EREG | c.278+1G>A p.X93_splice | Splice Site (SNP) | VAF 65/230 reads (28%) | catalogued as rs751004908, COSV55260608; called by muse, mutect2, varscan2
- ETNK1 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV56883684; called by muse, mutect2, varscan2
- FAM135B | c.3637A>G p.S1213G | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52704304, COSV52761905; called by muse, mutect2, varscan2
- FAM149A | c.922G>A p.E308K (on ENST00000356371 / NM_001367768.2; = p.E17K on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1034317509, COSV57025625; called by muse, mutect2, varscan2
- FAM155B | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV52935201; called by muse, mutect2, varscan2
- FAM83E | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52374412, COSV52377840; called by muse, mutect2, varscan2
- FAM8A1 | c.1242A>G p.*414Wext*6 | Nonstop Mutation (SNP) | VAF 32/134 reads (24%) | catalogued as COSV52580359; called by muse, varscan2
- FAN1 | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62949651; called by muse, mutect2, varscan2
- FANCD2OS | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs761646855, COSV55032545; called by muse, mutect2
- FAT1 | c.10067C>T p.T3356M | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); catalogued as rs760734038, COSV71671884; called by muse, mutect2, varscan2
- FATE1 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs1050509685, COSV64848825; called by muse, mutect2, varscan2
- FAXDC2 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 33/634 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58171264; called by muse, mutect2
- FBXO24 | c.131del p.P44Qfs*63 (on ENST00000241071 / NM_033506.3; = p.P82Qfs*63 on NM_012172.5) | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs1311766618, COSV99575673; called by mutect2, pindel, varscan2
- FBXW2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV61596413; called by muse, mutect2, varscan2
- FER1L6 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs762336156, COSV67547998; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 30/119 reads (25%) | catalogued as rs748969702; called by mutect2, varscan2
- FGFR1 | c.2222C>A p.P741H (on ENST00000447712 / NM_023110.3; = p.P739H on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412615365, COSV58327411; called by muse, mutect2
- FHL1 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs139402062, COSV61779675; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FKBP4 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780740336, COSV50008803; called by muse, mutect2, varscan2
- FLNB | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.153); catalogued as rs368617386; called by muse, mutect2, varscan2
- FMO1 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV61444592; called by muse, mutect2, varscan2
- FMR1 | c.1585G>T p.G529* | Nonsense Mutation (SNP) | VAF 72/311 reads (23%) | catalogued as COSV54421442; called by muse, mutect2, varscan2
- FOXD4L1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs773095229, COSV52072805; called by muse, mutect2
- FREM2 | c.4243G>A p.G1415R | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs775637631, COSV54827971; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 29/74 reads (39%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GABRA4 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51922313; called by muse, mutect2, varscan2
- GADL1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.967); catalogued as COSV56974775; called by muse, mutect2
- GALNT1 | c.1432A>G p.T478A | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1478393252, COSV52450789; called by muse, mutect2, varscan2
- GALNT18 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV57143717; called by muse, mutect2, varscan2
- GALNT2 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV64192813; called by muse, mutect2, varscan2
- GAREM1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs762101462, COSV52505737, COSV99330147; called by muse, mutect2, varscan2
- GART | c.3022A>G p.K1008E | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV67817946; called by muse, mutect2, varscan2
- GAS8 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200219366, COSV51942065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GK | c.922A>G p.T308A (on ENST00000427190 / NM_001205019.2; = p.T302A on NM_000167.6) | Missense Mutation (SNP) | VAF 93/310 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV66735486; called by muse, mutect2, varscan2
- GLB1 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs186781398, COSV56561276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLCCI1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 113/344 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773042027, COSV56200004; called by muse, mutect2, varscan2
- GLI3 | c.3701G>A p.S1234N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV67885128; called by muse, mutect2, varscan2
- GLT1D1 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV55878296; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 34/140 reads (24%) | catalogued as rs752075537; called by mutect2, varscan2
- GNB4 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 119/340 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145682913; called by muse, mutect2, varscan2
- GPBP1L1 | c.140A>G p.H47R | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767795611, COSV51966931; called by muse, varscan2
- GPI | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs750708328, COSV62893206; called by muse, mutect2, varscan2
- GPR142 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs201564934, COSV59518511; called by muse, mutect2, varscan2
- GPR20 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66683852; called by muse, mutect2, varscan2
- GRIN2A | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746978701, COSV58019618; called by muse, mutect2, varscan2
- GRIN2A | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs750050760, COSV58019636; called by muse, mutect2, varscan2
- GRK5 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs769347901, COSV64865548; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 17/153 reads (11%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- HCN1 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1252725512, COSV57493395; ClinVar: benign; called by muse, mutect2, varscan2
- HCN1 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV57493402; called by muse, mutect2, varscan2
- HCN4 | c.1997G>C p.R666P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV56081232; called by muse, mutect2
- HEATR5A | c.3775dup p.R1259Kfs*6 | Frame Shift Ins (INS) | VAF 38/241 reads (16%) | catalogued as rs767975930; called by mutect2, varscan2
- HECTD3 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs372991421; called by muse, mutect2, varscan2
- HECW2 | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as rs1242285702, COSV53648868; called by muse, mutect2, varscan2
- HGS | c.1447del p.A483Rfs*2 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1555699517, COSV100230656; called by mutect2, pindel, varscan2
- HGSNAT | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 99/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52816229; called by muse, mutect2, varscan2
- HINFP | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as rs1258883497, COSV63431603; called by muse, mutect2, varscan2
- HIVEP3 | c.6244C>T p.R2082W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs561486493, COSV56009458; called by mutect2, varscan2
- HIVEP3 | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56009472, COSV56013611; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPA2B1 | c.982G>T p.G328W (on ENST00000354667 / NM_031243.3; = p.G316W on NM_002137.4) | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61157996; called by muse, mutect2
- HORMAD1 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100464183, COSV59270158; called by muse, mutect2, varscan2
- HS1BP3 | c.199-1G>A p.X67_splice | Splice Site (SNP) | VAF 75/232 reads (32%) | catalogued as COSV58311886; called by muse, mutect2, varscan2
- HSPA4L | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.975); catalogued as COSV56543545; called by muse, mutect2, varscan2
- HSPA6 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368946919, COSV59059838; called by muse, mutect2, varscan2
- HUNK | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1359107822, COSV54224432; called by muse, mutect2, varscan2
- HYOU1 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs782303315, COSV68215129; called by muse, mutect2, varscan2
- IARS2 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56957460; called by muse, varscan2
- IDUA | c.842A>C p.Q281P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.366); catalogued as COSV56101391; called by muse, mutect2, varscan2
- IFI35 | c.21+1G>A p.X7_splice | Splice Site (SNP) | VAF 98/311 reads (32%) | catalogued as rs763757077, COSV53814495; called by muse, mutect2, varscan2
- IFT27 | c.77G>A p.R26H (on ENST00000433985 / NM_001363003.2; = p.R25H on NM_006860.5) | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs185871181; called by muse, mutect2, varscan2
- IGFBP5 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); catalogued as COSV52081998; called by muse, mutect2, varscan2
- IK | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.375); catalogued as rs538502414, COSV70257358; called by muse, mutect2, varscan2
- IL12A | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as rs376766194; called by muse, mutect2, varscan2
- IL1RL2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs1350560105, COSV51812885; called by muse, mutect2, varscan2
- INCENP | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs778533228, COSV53913121; called by muse, mutect2, varscan2
- INO80 | c.4478A>G p.Q1493R | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV62736048; called by muse, mutect2, varscan2
- INSYN2A | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs143671561; called by muse, varscan2
- INSYN2A | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as COSV54729498; called by muse, varscan2
- INTS1 | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs370265253; called by muse, mutect2, varscan2
- INTS8 | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 19/274 reads (7%) | catalogued as COSV58248494; called by muse, mutect2
- IQGAP3 | c.4312C>T p.R1438W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs374144760; called by muse, mutect2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 53/209 reads (25%) | catalogued as rs780982673; called by mutect2, varscan2
- IRX6 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs138532658; called by muse, mutect2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, pindel, varscan2
- ITGAL | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV63320000; called by muse, mutect2
- ITGAM | c.1948G>A p.G650R (on ENST00000648685 / NM_001145808.2; = p.G649R on NM_000632.4) | Missense Mutation (SNP) | VAF 119/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763736373, COSV54933790; called by muse, mutect2, varscan2
- ITIH6 | c.3899T>C p.V1300A | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV54486360; called by muse, mutect2, varscan2
- IYD | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57599278; called by muse, mutect2, varscan2
- KALRN | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53752704; called by muse, mutect2, varscan2
- KAT2B | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs767911128, COSV55426452; called by muse, mutect2, varscan2
- KCNB1 | c.2206dup p.R736Pfs*4 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | catalogued as rs759902465; called by mutect2, varscan2
- KCNE2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV51709563; called by muse, mutect2, varscan2
- KCNH6 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs760521267, COSV59000655; called by muse, mutect2, varscan2
- KCNH6 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs142210523; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KCTD18 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as COSV63343916; called by muse, mutect2, varscan2
- KDM4D | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as rs782744103, COSV58633494; called by muse, mutect2, varscan2
- KIAA0408 | c.1925T>C p.V642A | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as rs1211585348, COSV64115729; called by muse, mutect2, varscan2
- KIDINS220 | c.3242del p.P1081Rfs*48 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV56750269; called by mutect2, pindel, varscan2
- KIF26B | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs781404705, COSV63636602; called by muse, mutect2, varscan2
- KIF2B | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779737986, COSV52126920, COSV52127326; called by muse, mutect2
- KIF4A | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753323782, COSV65541243; called by muse, mutect2, varscan2
- KIT | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145602440, COSV55388252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL10 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53172614; called by muse, mutect2
- KLK10 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs753880851, COSV59397280; called by muse, mutect2, varscan2
- KMT2B | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs1011328460, COSV52889326; called by muse, mutect2, varscan2
- KMT2B | c.5730del p.R1911Dfs*23 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV55867385; called by mutect2, pindel, varscan2
- KMT2B | c.6995G>A p.R2332H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs758088530, COSV55856608; called by muse, mutect2, varscan2
- KRT16 | c.197del p.G66Afs*54 | Frame Shift Del (DEL) | VAF 35/108 reads (32%) | catalogued as rs1555573913; called by mutect2, pindel, varscan2
- KRT71 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as rs1466712531, COSV57288885; called by muse, mutect2, varscan2
- KSR1 | c.566G>A p.R189Q (on ENST00000644974 / NM_001367810.1; = p.R52Q on NM_014238.2) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs1199776213, COSV52028179; called by muse, mutect2, varscan2
- KTN1 | c.3256C>A p.P1086T (on ENST00000395314 / NM_001271014.2; = p.P1057T on NM_004986.4) | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58539870; called by muse, mutect2, varscan2
- L3MBTL3 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.088); catalogued as rs374581461; called by muse, mutect2, varscan2
- LAMA1 | c.2296G>A p.G766S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs575091797, COSV67531894, COSV67532108; called by muse, mutect2, varscan2
- LATS1 | c.1949T>C p.V650A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV53586091; called by muse, mutect2
- LGALS14 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100648425, COSV62372145; called by muse, mutect2, varscan2
- LILRA1 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV52177793; called by muse, mutect2, varscan2
- LIN9 | c.1081C>T p.R361W (on ENST00000366808 / NM_001270410.2; = p.R306W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60243786; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 126/420 reads (30%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMTK2 | c.4328T>C p.L1443P | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV51990218; called by muse, mutect2, varscan2
- LPAR1 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.474); catalogued as COSV62687021; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs762083435; called by mutect2, varscan2
- LRCH3 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58388670; called by muse, mutect2, varscan2
- LRFN2 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57823665; called by muse, mutect2, varscan2
- LRP2 | c.4211G>A p.C1404Y | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535034303, COSV55540519; called by muse, mutect2, varscan2
- LRRC17 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV50863983; called by muse, mutect2
- LRRC8E | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as rs147444920; called by muse, mutect2, varscan2
- LRRN1 | c.783del p.V262Ffs*4 | Frame Shift Del (DEL) | VAF 43/126 reads (34%) | catalogued as COSV100076048; called by mutect2, pindel, varscan2
- LTBP1 | c.4745C>T p.T1582M (on ENST00000404816 / NM_206943.4; = p.T1256M on NM_000627.4) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs534680091, COSV55375405; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs754757253, COSV52588935; called by mutect2, pindel, varscan2
- LYPD2 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765580069, COSV63649061; called by muse, mutect2, varscan2
- LYST | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 115/387 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1207508988, COSV67703194; called by muse, mutect2, varscan2
- MACF1 | c.18803del p.N6268Mfs*32 (on ENST00000372915; = p.N4313Mfs*32 on NM_012090.5) | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | catalogued as rs748961150; called by mutect2, pindel, varscan2
- MAD2L2 | c.425del p.P142Qfs*45 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as COSV99336009; called by mutect2, pindel, varscan2
- MAGEA6 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150966954, COSV61448665; called by muse, mutect2, varscan2
- MAGIX | c.251A>C p.H84P | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs782405786, COSV66255656; called by muse, mutect2, varscan2
- MAP3K4 | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770796845, COSV62330097; called by muse, mutect2, varscan2
- MAP4K4 | c.1637G>T p.R546M (on ENST00000347699 / NM_001242559.2; = p.R515M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV56324771; called by muse, mutect2, varscan2
- MARVELD2 | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as COSV57779471; called by muse, mutect2, varscan2
- MASP1 | c.1895C>A p.A632D | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61824138; called by muse, mutect2, varscan2
- MCCC1 | c.626del p.G209Vfs*7 | Frame Shift Del (DEL) | VAF 57/205 reads (28%) | catalogued as CM1510822; called by mutect2, pindel, varscan2
- MCF2L2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs766191962, COSV61049044; called by muse, mutect2
- MDGA1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as rs369840766; called by muse, mutect2, varscan2
- MED13 | c.6331G>A p.E2111K | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101181018, COSV67261863; called by muse, mutect2, varscan2
- MED13 | c.3091C>T p.Q1031* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV67261867; called by muse, mutect2, varscan2
- MED24 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV62416949; called by muse, mutect2
- MGAT5B | c.2056G>A p.A686T (on ENST00000569840 / NM_001199172.2; = p.A684T on NM_144677.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1405678969, COSV56924909, COSV56934271; called by mutect2, varscan2
- MKI67 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759351634, COSV64072489; called by muse, mutect2, varscan2
- MLKL | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58204034; called by muse, mutect2, varscan2
- MLN | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV56474746; called by muse, mutect2, varscan2
- MLXIP | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs374468907; called by muse, mutect2, varscan2
- MPEG1 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57088184; called by muse, mutect2, varscan2
- MROH5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs371849930; called by muse, mutect2
- MRPL20 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV61223983; called by muse, mutect2, varscan2
- MS4A1 | c.67A>T p.M23L | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61941622; called by muse, mutect2, varscan2
- MS4A8 | c.219+1del | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as rs751198816; called by mutect2, pindel, varscan2
- MSH2 | c.1613dup p.N538Kfs*3 | Frame Shift Ins (INS) | VAF 40/166 reads (24%) | catalogued as rs1558511092; called by mutect2, pindel, varscan2
- MSTN | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV53620262; called by muse, mutect2, varscan2
- MTF2 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 73/256 reads (29%) | catalogued as COSV64769457; called by muse, mutect2, varscan2
- MTMR7 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029814845, COSV51662950; called by muse, mutect2, varscan2
- MTUS1 | c.1237T>G p.W413G | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.359); catalogued as COSV50550657; called by muse, mutect2, varscan2
- MUC16 | c.41754C>T p.T13918= | Splice Region (SNP) | VAF 55/171 reads (32%) | catalogued as rs755849764, COSV66689741; called by muse, mutect2, varscan2
- MUC5B | c.10282G>A p.A3428T | Missense Mutation (SNP) | VAF 155/739 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as COSV71589941, COSV71594938; called by muse, mutect2, varscan2
- MYH10 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs147765876; called by muse, varscan2
- MYH14 | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51810143; called by muse, mutect2, varscan2
- MYH6 | c.5660C>T p.A1887V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs767096302, COSV59304590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62516204; called by muse, mutect2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1C | c.1078G>A p.A360T (on ENST00000648651 / NM_001080779.2; = p.A325T on NM_033375.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as COSV62998312; called by muse, mutect2
- MYO5B | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53210932; called by muse, mutect2, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as COSV58513333; called by mutect2, pindel, varscan2
- MYPN | c.2402T>C p.I801T | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV62731495, COSV62733022; called by muse, mutect2, varscan2
- NALCN | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 143/442 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as rs1270231284, COSV51916991; called by muse, mutect2, varscan2
- NARF | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs200008071, COSV100559607; called by muse, mutect2, varscan2
- NCAM2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs765814157, COSV53055753; called by muse, mutect2, varscan2
- NCR1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as rs777127236, COSV52555308; called by muse, mutect2, varscan2
- NDUFA9 | c.657T>C p.S219= | Splice Region (SNP) | VAF 19/520 reads (4%) | catalogued as COSV56927687; called by muse, mutect2
- NEDD4L | c.2846C>A p.P949H (on ENST00000400345 / NM_001144967.3; = p.P929H on NM_015277.6) | Missense Mutation (SNP) | VAF 148/418 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56840083; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NIT1 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV63501127; called by muse, mutect2, varscan2
- NLGN2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs777369347, COSV100259412, COSV57208907; called by muse, mutect2, varscan2
- NLRP4 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs768393472, COSV56707698; called by muse, mutect2, varscan2
- NOS1 | c.2027dup p.C677Lfs*38 | Frame Shift Ins (INS) | VAF 25/98 reads (26%) | catalogued as rs746543323; called by mutect2, varscan2
- NOTCH3 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV99658020; called by muse, varscan2
- NPAS2 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59555214; called by muse, mutect2, varscan2
- NPHP4 | c.3111G>T p.E1037D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65393052; called by muse, mutect2, varscan2
- NPY2R | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.094); catalogued as COSV61527161; called by muse, mutect2
- NPY4R | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782543479, COSV100966134, COSV65397467; called by muse, mutect2, varscan2
- NRAP | c.2528C>T p.S843L (on ENST00000359988 / NM_001322945.2; = p.S808L on NM_006175.4) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs144314453; called by muse, mutect2, varscan2
- NSD1 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 50/132 reads (38%) | catalogued as CM030068, COSV61770550; called by muse, mutect2, varscan2
- NSD3 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 106/331 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs777597698, COSV57617110; called by muse, mutect2, varscan2
- NTHL1 | c.248A>G p.K83R (on ENST00000219066; = p.K75R on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54592241; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 80/229 reads (35%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP35 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV54556976; called by muse, mutect2, varscan2
- NUP37 | c.408A>C p.E136D | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV51837075; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 56/179 reads (31%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OBI1 | c.953G>C p.S318T | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV56144420; called by muse, mutect2, varscan2
- OPRPN | c.390dup p.L131Sfs*9 | Frame Shift Ins (INS) | VAF 196/592 reads (33%) | catalogued as rs1560534905; called by mutect2, varscan2
- OR10P1 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV59006675; called by muse, mutect2, varscan2
- OR1E1 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59458392; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 41/146 reads (28%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OR52D1 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV59486945; called by muse, mutect2, varscan2
- OR56A1 | c.911_912del p.Q304Rfs*14 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs767406765, COSV57361762; called by mutect2, pindel, varscan2
- OR5W2 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV60614590; called by muse, mutect2, varscan2
- OR8G1 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV58379682; called by muse, mutect2, varscan2
- ORC1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs141623460; called by muse, mutect2, varscan2
- OTUD7B | c.1952A>C p.K651T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV64915030; called by muse, mutect2, varscan2
- PALB2 | c.886del p.M296* | Frame Shift Del (DEL) | VAF 33/135 reads (24%) | catalogued as CD147527; called by mutect2, pindel, varscan2
- PAQR9 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV61417552; called by muse, mutect2, varscan2
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 144/427 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 46/191 reads (24%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAX8 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV54506346; called by muse, varscan2
- PCBP3 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs916264253, COSV68406497; called by muse, mutect2, varscan2
- PCDHB2 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50564064; called by muse, mutect2, varscan2
- PCDHGA3 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as COSV53897290; called by muse, mutect2, varscan2
- PEAK1 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56930541, COSV56938889; called by muse, mutect2
- PEG10 | c.818C>T p.P273L (on ENST00000482108 / NM_001040152.2; = p.P307L on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV71787954, COSV71788016; called by mutect2, varscan2
- PEX11B | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782292493, COSV65195960; called by muse, mutect2, varscan2
- PFN1 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV52590294; called by muse, mutect2, varscan2
- PHLDB2 | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as COSV67307798; called by muse, mutect2
- PHRF1 | c.4240G>A p.A1414T (on ENST00000264555 / NM_001286581.2; = p.A1413T on NM_020901.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs1365830435, COSV52750937; called by muse, varscan2
- PIDD1 | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV57192268; called by muse, varscan2
- PIP4P1 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51656935; called by muse, mutect2, varscan2
- PKP4 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs774001615, COSV61577779; called by muse, mutect2
- PLCB2 | c.3497del p.P1166Qfs*10 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | catalogued as COSV53036546; called by mutect2, pindel, varscan2
- PLCB3 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192862173, COSV54185686; called by muse, mutect2, varscan2
- PLCG1 | c.2879G>A p.C960Y | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54815126; called by muse, mutect2, varscan2
- PLCXD1 | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58204419; called by muse, mutect2, varscan2
- PLXNA2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65437548; called by muse, mutect2, varscan2
- PNPLA2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs746987189, COSV60743788; called by muse, mutect2, varscan2
- PNPLA7 | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537805357, COSV52994072; called by muse, mutect2, varscan2
- POLRMT | c.3406G>A p.A1136T | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs550982985, COSV52112348; called by muse, mutect2, varscan2
- POMGNT1 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | PolyPhen probably damaging (0.995); catalogued as rs755588045, COSV64339314; called by muse, mutect2, varscan2
- POU3F4 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs1189457059, COSV100937199, COSV64537705, COSV64538282; called by muse, mutect2, varscan2
- PPFIA4 | c.2459G>A p.R820H (on ENST00000447715; = p.R821H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); catalogued as rs547227552, COSV55311201; called by muse, mutect2, varscan2
- PPP1R12A | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV54105263; called by muse, mutect2, varscan2
- PPP1R14C | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as rs1425033513, COSV63172619; called by muse, mutect2, varscan2
- PPP4R1 | c.1570A>G p.K524E (on ENST00000400556 / NM_001042388.3; = p.K507E on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as COSV53280327; called by muse, mutect2
- PRCP | c.889T>C p.F297L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV57287344; called by muse, mutect2, varscan2
- PRDM11 | c.1348C>T p.R450C (on ENST00000530656 / NM_001359633.1; = p.R416C on NM_001256695.1) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753240285, COSV55437400; called by muse, mutect2, varscan2
- PRDM15 | c.735C>T p.H245= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as rs775842920, COSV54148743; called by muse, mutect2, varscan2
- PRDX6 | c.520dup p.R174Kfs*7 | Frame Shift Ins (INS) | VAF 60/198 reads (30%) | catalogued as rs1557998081; called by mutect2, pindel, varscan2
- PREB | c.1198G>T p.G400W | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV53204434; called by muse, mutect2, varscan2
- PRKD1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59559214, COSV59571415; called by muse, mutect2, varscan2
- PRPF8 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59260487; called by muse, mutect2
- PRR14L | c.5590C>T p.R1864W | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751253317, COSV57882730; called by muse, mutect2, varscan2
- PRRC2B | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV61933719; called by muse, mutect2, varscan2
- QPRT | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.936); catalogued as rs1306590993, COSV54879078; called by muse, mutect2, varscan2
- R3HDML | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53835130; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51930223; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1956dup p.K653Qfs*112 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | catalogued as rs755409958; called by mutect2, varscan2
- RAB40C | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50192827; called by muse, mutect2, varscan2
- RADX | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as COSV65317790; called by muse, mutect2, varscan2
- RANBP3 | c.145del p.H49Tfs*15 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs865971344; called by mutect2, pindel, varscan2
- RAPGEF6 | c.2581A>G p.T861A | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.336); catalogued as COSV57239941; called by muse, mutect2, varscan2
- RASGRF2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766478295, COSV54122691; called by muse, mutect2, varscan2
- RECK | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs749822134, COSV65034561; called by muse, mutect2, varscan2
- REG1A | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs374824380; called by muse, mutect2
- RELN | c.5473A>G p.R1825G | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as COSV58985357; called by muse, varscan2
- RELN | c.5405C>T p.S1802L | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1290597164, COSV58985363; called by muse, varscan2
- RGL2 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750813145, COSV65841907; called by muse, mutect2, varscan2
- RING1 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV63002256; called by muse, mutect2, varscan2
- RINT1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs772540725, COSV57557297; called by muse, mutect2, varscan2
- RNF32 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs375486401; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPEPL1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759412567, COSV54371804; called by muse, mutect2, varscan2
- RNPS1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.973); catalogued as rs140623716; called by muse, mutect2, varscan2
- ROBO2 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762706045, COSV59896012; called by muse, mutect2, varscan2
- RPA1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54607170; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 52/133 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRP12 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180948672, COSV59664686; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as rs759252078; called by mutect2, varscan2
- RYR1 | c.12118G>A p.A4040T | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs374441925; called by muse, mutect2, varscan2
- SATB1 | c.1946C>G p.T649R | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58667389; called by muse, mutect2, varscan2
- SCFD2 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs759798881, COSV66368668; called by muse, mutect2, varscan2
- SCML1 | c.596A>G p.D199G (on ENST00000380041 / NM_001037540.3; = p.D172G on NM_006746.6) | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV66240362; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 41/131 reads (31%) | catalogued as rs765136101; called by mutect2, varscan2
- SCUBE3 | c.2878del p.Q960Rfs*30 | Frame Shift Del (DEL) | VAF 36/137 reads (26%) | catalogued as COSV99233947; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 85/230 reads (37%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SERPINA1 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749295615, COSV63345326; called by muse, mutect2, varscan2
- SERPINB9 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV66232884; called by muse, mutect2, varscan2
- SESN3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1400088899, COSV53583259; called by muse, mutect2, varscan2
- SH3GL2 | c.1059G>T p.*353Yext*17 | Nonstop Mutation (SNP) | VAF 51/163 reads (31%) | catalogued as COSV66047558; called by muse, mutect2, varscan2
- SH3PXD2B | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61124643; called by muse, mutect2, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as COSV53462966; called by mutect2, varscan2
- SHROOM2 | c.4663C>T p.R1555C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66604484; called by muse, mutect2, varscan2
- SIGLEC12 | c.866G>T p.R289M (on ENST00000291707 / NM_053003.4; = p.R171M on NM_033329.2) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as COSV52459217; called by muse, mutect2, varscan2
- SLA | c.131G>A p.R44H (on ENST00000338087 / NM_001045556.3; = p.R84H on NM_006748.4) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs201581025; called by muse, mutect2, varscan2
- SLC12A8 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.456); catalogued as rs775399116, COSV58863097; called by muse, mutect2, varscan2
- SLC20A2 | c.1913C>A p.A638D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60601531; called by muse, mutect2, varscan2
- SLC23A1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755738741, COSV62295873; called by muse, mutect2, varscan2
- SLC26A6 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV56569919; called by muse, mutect2, varscan2
- SLC34A2 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 31/453 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65940569; called by muse, mutect2
- SLC35D2 | c.851T>A p.I284N | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53561552; called by muse, mutect2, varscan2
- SLC35E1 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs1408146172, COSV68735624; called by muse, mutect2, varscan2
- SLC35F6 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442546290, COSV60426009; called by muse, mutect2, varscan2
- SLC41A1 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV65650041; called by muse, mutect2
- SLC7A1 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66329539; called by muse, mutect2, varscan2
- SLC7A5 | c.1384T>C p.F462L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as rs1387201010, COSV55362891; called by muse, mutect2, varscan2
- SLC9A5 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs753560981, COSV55360137; called by muse, mutect2, varscan2
- SLC9A9 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57217690; called by muse, mutect2, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | catalogued as rs747319777; called by mutect2, varscan2
- SLIT3 | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766926263, COSV60592115; called by muse, mutect2, varscan2
- SLTM | c.1879C>T p.R627* | Nonsense Mutation (SNP) | VAF 123/422 reads (29%) | catalogued as COSV51053263; called by muse, mutect2, varscan2
- SLX4 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs775151113, COSV53560765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD3 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs1320208623, COSV59280371; called by muse, mutect2, varscan2
- SMOX | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1420253080, COSV53862903; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 23/43 reads (53%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SNTG2 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57967708; called by muse, mutect2, varscan2
- SNX19 | c.2828A>G p.Q943R | Missense Mutation (SNP) | VAF 90/295 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1442074917, COSV56283787; called by muse, mutect2, varscan2
- SOCS2 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV61391910; called by muse, mutect2, varscan2
- SOD2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs756878036, COSV61622782; called by muse, varscan2
- SOGA1 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52911389; called by muse, mutect2, varscan2
- SOHLH2 | c.750A>T p.K250N | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65901099, COSV65902508; called by muse, mutect2, varscan2
- SOWAHB | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs770452590, COSV57554050; called by muse, mutect2, varscan2
- SP100 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.391); catalogued as COSV50974465; called by muse, mutect2, varscan2
- SPARCL1 | c.839del p.N280Mfs*23 | Frame Shift Del (DEL) | VAF 149/538 reads (28%) | catalogued as rs1179774720, COSV56803070; called by mutect2, pindel, varscan2
- SPHK2 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1331695105, COSV55334728; called by muse, mutect2, varscan2
- SPINK5 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs761863957, COSV56248505; called by muse, varscan2
- SPNS3 | c.1382del p.G461Afs*6 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs756918252; called by mutect2, pindel, varscan2
- SPTA1 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63748710; called by muse, mutect2, varscan2
- SPTB | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as rs1024800811, COSV67629729, COSV67632569; called by muse, mutect2, varscan2
- SRRT | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs138829624; called by muse, mutect2, varscan2
- SRSF6 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54826944; called by muse, mutect2, varscan2
- ST6GAL1 | c.461A>C p.E154A | Missense Mutation (SNP) | VAF 40/119 reads (34%) | PolyPhen benign (0.071); catalogued as COSV51466025; called by muse, mutect2, varscan2
- STAM | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV66324858; called by muse, mutect2
- STAT1 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV63115006; called by muse, mutect2, varscan2
- STOML2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1313882943, COSV58925166; called by muse, mutect2, varscan2
- STXBP2 | c.88-1G>A p.X30_splice | Splice Site (SNP) | VAF 32/90 reads (36%) | catalogued as CS108415, COSV55401745; called by muse, mutect2, varscan2
- SUCLG2 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56201635, COSV56207829; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 42/164 reads (26%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 79/257 reads (31%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- TAB1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs774694760, COSV53369980; called by muse, mutect2, varscan2
- TAB3 | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV55834252; called by muse, mutect2, varscan2
- TANC1 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1425593535, COSV55082824, COSV55093743; called by muse, mutect2
- TARS2 | c.2082G>T p.W694C | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.643); catalogued as COSV60871656; called by muse, mutect2, varscan2
- TBRG4 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143689271; called by muse, mutect2, varscan2
- TCERG1 | c.1881dup p.R628Tfs*6 | Frame Shift Ins (INS) | VAF 17/79 reads (22%) | catalogued as rs751330927; called by mutect2, varscan2
- TDGF1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as rs749372682, COSV56124885; called by muse, mutect2, varscan2
- TDP2 | c.71del p.K24Sfs*35 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV57765402; called by mutect2, pindel, varscan2
- TEKT1 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.515); catalogued as COSV58622055; called by muse, mutect2, varscan2
- TENM4 | c.3901C>T p.R1301W | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV53607775; called by muse, mutect2, varscan2
- TEPSIN | c.1350del p.G452Afs*72 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs745976991, COSV56142035; called by mutect2, varscan2
- TEX19 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV61016888; called by muse, mutect2, varscan2
- TEX35 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs760953202, COSV51103208; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 70/184 reads (38%) | catalogued as rs746975641; called by mutect2, varscan2
- TJP2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs755935175, COSV55262343; called by muse, mutect2, varscan2
- TKFC | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs756338140, COSV67523197; called by muse, mutect2, varscan2
- TKT | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139724440; called by muse, mutect2, varscan2
- TMBIM1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV50310785; called by muse, mutect2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 43/108 reads (40%) | catalogued as rs754390908; called by mutect2, varscan2
- TMEM106C | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56742152; called by muse, mutect2, varscan2
- TMEM11 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV58312750; called by muse, mutect2
- TMEM186 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51630725; called by muse, mutect2, varscan2
- TMEM59L | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.88); catalogued as COSV53241512; called by muse, mutect2, varscan2
- TMEM63B | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52476950; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs747222326; called by pindel, varscan2
- TMPRSS2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372563970; called by muse, mutect2, varscan2
- TMTC3 | c.1429C>G p.P477A | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV57122271; called by muse, mutect2, varscan2
- TNNI3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 107/329 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs760978512, COSV52570286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC6A | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.805); catalogued as rs1017051791, COSV59361072; called by muse, mutect2
- TONSL | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs771375609, COSV68047562; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 32/290 reads (11%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TOPORS | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.439); catalogued as COSV62116112; called by muse, mutect2, varscan2
- TP53BP1 | c.4324C>T p.R1442* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV55496246; called by muse, mutect2, varscan2
- TP53BP2 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV59066139; called by muse, mutect2, varscan2
- TP63 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.353); catalogued as COSV53202068; called by muse, mutect2
- TPCN1 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 91/424 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs764627251, COSV59232206; called by muse, mutect2, varscan2
- TPTE | c.871G>T p.D291Y (on ENST00000618007 / NM_199261.4; = p.D273Y on NM_199259.4) | Missense Mutation (SNP) | VAF 75/542 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs373367615; called by muse, mutect2, varscan2
- TREX2 | c.418G>A p.V140M (on ENST00000334497; = p.V97M on NM_080701.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs782119886, COSV57847763; called by muse, mutect2
- TRGV3 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs755878126; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as rs148620646; called by muse, mutect2, varscan2
- TRIM54 | c.740G>A p.R247H (on ENST00000380075 / NM_187841.3; = p.R289H on NM_032546.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs142379604; called by muse, mutect2, varscan2
- TRPV1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765271282, COSV51515068; called by muse, mutect2, varscan2
- TRPV4 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.658); catalogued as rs114874026, COSV55679769; called by mutect2, varscan2
- TSGA13 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV58404130; called by muse, mutect2, varscan2
- TSPAN17 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs374273809; called by muse, mutect2, varscan2
- TSSK6 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773232969, COSV53062512; called by mutect2, varscan2
- TTC14 | c.903del p.K301Nfs*8 | Frame Shift Del (DEL) | VAF 52/190 reads (27%) | catalogued as rs1560072646; called by mutect2, pindel, varscan2
- TTC4 | c.818G>T p.R273M | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); catalogued as COSV64884341; called by muse, mutect2, varscan2
- TTF1 | c.821del p.K274Sfs*149 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs770528448; called by mutect2, varscan2
- TTI1 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65060391, COSV65060564; called by muse, mutect2, varscan2
- TTN | c.49610G>A p.R16537H (on ENST00000591111; = p.R9113H on NM_003319.4) | Missense Mutation (SNP) | VAF 86/284 reads (30%) | PolyPhen benign (0.007); catalogued as rs879023208, COSV100593367, COSV59882664; called by muse, mutect2, varscan2
- TUBGCP6 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867932672, COSV50536430; called by muse, mutect2, varscan2
- TXLNA | c.285del p.G96Afs*33 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV101009821; called by mutect2, pindel, varscan2
- UBE2E2 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59965378; called by muse, mutect2, varscan2
- UBR4 | c.4342C>T p.H1448Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV64382717; called by muse, mutect2, varscan2
- UBXN1 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); catalogued as rs1039598952, COSV53656054; called by muse, mutect2
- UCHL1 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV52650898; called by muse, mutect2, varscan2
- UCKL1 | c.916A>G p.S306G | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62402260; called by muse, mutect2, varscan2
- UHRF1 | c.2320G>A p.V774M (on ENST00000612630 / NM_001290050.1; = p.V787M on NM_013282.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs1350033092, COSV53573196; called by muse, mutect2, varscan2
- UNC5A | c.293-1G>T p.X98_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | catalogued as COSV56165318; called by muse, mutect2, varscan2
- UPRT | c.563-1G>T p.X188_splice | Splice Site (SNP) | VAF 62/188 reads (33%) | catalogued as COSV64919946; called by muse, mutect2, varscan2
- USF1 | c.389del p.G130Vfs*33 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs1374448785; called by mutect2, varscan2
- USH2A | c.9750C>A p.C3250* | Nonsense Mutation (SNP) | VAF 54/121 reads (45%) | catalogued as COSV56326490; called by muse, mutect2, varscan2
- USH2A | c.8284C>T p.P2762S | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as CM148280, COSV56326513, COSV56435934; called by muse, mutect2, varscan2
- USP10 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54746876; called by muse, mutect2, varscan2
- USP20 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs769753156, COSV59610920; called by muse, mutect2
- USP25 | c.1198T>C p.Y400H | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53480707; called by muse, mutect2
- USP30 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs367566462, COSV99980474; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 74/172 reads (43%) | catalogued as rs764735138; called by mutect2, varscan2
- USP48 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1379741064, COSV57607069; called by muse, mutect2
- UST | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764103894, COSV66545551; called by muse, mutect2, varscan2
- UTP18 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 113/440 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56582220; called by muse, mutect2, varscan2
- VASH1 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1419984167, COSV51335171; called by muse, mutect2
- VBP1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53971812; called by muse, mutect2, varscan2
- VPS13C | c.11105G>A p.S3702N (on ENST00000644861 / NM_020821.3; = p.S3659N on NM_017684.5) | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV51121111; called by muse, mutect2, varscan2
- VPS33A | c.1376del p.G459Afs*86 | Frame Shift Del (DEL) | VAF 66/292 reads (23%) | catalogued as rs1357715083, COSV57357082; called by mutect2, pindel, varscan2
- WAS | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV64996593; called by muse, mutect2, varscan2
- WDR27 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV61204280; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 36/113 reads (32%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR62 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV54331583; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 38/70 reads (54%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WWC1 | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777482969, COSV54645561; called by muse, mutect2, varscan2
- XIRP1 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs781339670, COSV61136784; called by muse, mutect2, varscan2
- XYLB | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs767754380, COSV52911397; called by muse, mutect2, varscan2
- ZBED9 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.015); catalogued as COSV71729152; called by muse, mutect2, varscan2
- ZBTB16 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as rs753220958, COSV60089123; called by muse, mutect2, varscan2
- ZBTB4 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV60976607; called by muse, mutect2
- ZC3H18 | c.318A>C p.E106D | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.114); catalogued as COSV56322494; called by muse, mutect2, varscan2
- ZDHHC1 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62214547; called by muse, mutect2, varscan2
- ZFR | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1425782502, COSV54050332, COSV54053878; called by muse, mutect2, varscan2
- ZFYVE26 | c.5275C>T p.L1759F | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.662); catalogued as COSV61324281; called by muse, varscan2
- ZHX2 | c.2434A>T p.S812C | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs1369602118, COSV58710135; called by muse, mutect2, varscan2
- ZKSCAN8 | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.076); catalogued as COSV57636894; called by muse, mutect2, varscan2
- ZMYND8 | c.1904del p.K635Sfs*14 (on ENST00000311275 / NM_001363741.2; = p.K655Sfs*14 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 92/318 reads (29%) | catalogued as rs776813452; called by mutect2, varscan2
- ZNF236 | c.1381del p.M461* | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as rs769237443, COSV53487827; called by mutect2, varscan2
- ZNF250 | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV52967861; called by muse, mutect2, varscan2
- ZNF362 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as rs758516719, COSV65031034; called by muse, mutect2, varscan2
- ZNF366 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748770091, COSV59213686; called by muse, mutect2, varscan2
- ZNF443 | c.1997G>A p.R666K | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs1304847736, COSV56890111; called by muse, mutect2, varscan2
- ZNF500 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV54786978; called by muse, mutect2, varscan2
- ZNF530 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 30/442 reads (7%) | catalogued as COSV60530867; called by muse, mutect2
- ZNF578 | c.1765T>C p.S589P | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV69735915; called by muse, mutect2
- ZNF585A | c.458C>T p.A153V (on ENST00000292841 / NM_001288800.2; = p.A98V on NM_152655.3) | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV53061583; called by muse, mutect2, varscan2
- ZNF595 | c.1322T>C p.L441S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV59547162; called by muse, mutect2, varscan2
- ZNF648 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100374764, COSV60569628; called by muse, mutect2
- ZNF709 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 60/159 reads (38%) | catalogued as rs773646499, COSV67194142; called by muse, mutect2, varscan2
- ZNF710 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1042789622, COSV51561608; called by muse, mutect2, varscan2
- ZNF75D | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs781909943, COSV66132350; called by muse, mutect2
- ZNF776 | c.941A>G p.H314R | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57814372; called by muse, mutect2
- ZNF830 | c.753del p.F251Lfs*6 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | catalogued as rs749765261; called by mutect2, pindel, varscan2
- ZSWIM4 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as COSV54319191, COSV54319378; called by muse, mutect2
- ABCC4 | c.2648del p.L883Wfs*7 | Frame Shift Del (DEL) | VAF 27/181 reads (15%) | called by mutect2, pindel, varscan2
- ACACA | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); called by muse, mutect2
- ACRBP | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); called by muse, mutect2
- ADAMTSL1 | c.152del p.G51Vfs*7 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- AKAP13 | c.7511del p.K2504Rfs*50 (on ENST00000394518 / NM_007200.5; = p.K2508Rfs*50 on NM_006738.6) | Frame Shift Del (DEL) | VAF 71/319 reads (22%) | called by pindel, varscan2
- ARID4B | c.2408del p.K803Rfs*18 | Frame Shift Del (DEL) | VAF 97/406 reads (24%) | called by mutect2, pindel, varscan2
- ARID5B | c.2901del p.K967Nfs*15 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- ASCL4 | c.109del p.L37Sfs*53 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- ATRX | c.1074del p.K358Nfs*2 | Frame Shift Del (DEL) | VAF 92/250 reads (37%) | called by mutect2, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | called by mutect2, varscan2
- BACE1 | c.367del p.D123Tfs*24 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel
- BRD7 | c.233del p.K78Rfs*34 | Frame Shift Del (DEL) | VAF 140/525 reads (27%) | called by mutect2, pindel, varscan2
- C1QTNF2 | c.555dup p.C186Lfs*30 (on ENST00000393975; = p.C141Lfs*30 on NM_031908.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/64 reads (34%) | called by mutect2, pindel, varscan2
- C6orf89 | c.997del p.V333Sfs*18 (on ENST00000373685; = p.V340Sfs*18 on NM_152734.4) | Frame Shift Del (DEL) | VAF 16/161 reads (10%) | called by mutect2, pindel, varscan2
- CCDC173 | c.608_609del p.K203Sfs*23 | Frame Shift Del (DEL) | VAF 124/452 reads (27%) | called by mutect2, pindel, varscan2
- CCNK | c.336dup p.C113Mfs*2 | Frame Shift Ins (INS) | VAF 86/252 reads (34%) | called by mutect2, varscan2
- CEP350 | c.5174del p.K1725Nfs*24 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- CHD3 | c.378dup p.Q127Afs*27 | Frame Shift Ins (INS) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- CLCN2 | c.2134_2135del p.P713Hfs*22 | Frame Shift Del (DEL) | VAF 46/168 reads (27%) | called by pindel, varscan2
- COL19A1 | c.1473del p.G492Efs*8 | Frame Shift Del (DEL) | VAF 115/415 reads (28%) | called by mutect2, pindel, varscan2
- COL8A1 | c.2015del p.G672Afs*14 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- COX19 | c.270del p.K90Nfs*4 | Frame Shift Del (DEL) | VAF 139/441 reads (32%) | called by mutect2, pindel, varscan2
- CRACDL | c.99del p.F33Lfs*94 | Frame Shift Del (DEL) | VAF 62/231 reads (27%) | called by mutect2, pindel, varscan2
- CWC22 | c.121del p.R41Gfs*63 | Frame Shift Del (DEL) | VAF 51/255 reads (20%) | called by mutect2, pindel, varscan2
- DAPK1 | c.912dup p.W305Mfs*23 | Frame Shift Ins (INS) | VAF 89/339 reads (26%) | called by mutect2, pindel, varscan2
- DDX3X | c.1152del p.P385Lfs*12 (on ENST00000399959; = p.P386Lfs*12 on NM_001356.5) | Frame Shift Del (DEL) | VAF 104/336 reads (31%) | called by mutect2, pindel, varscan2
- DENND4A | c.4681del p.C1561Afs*61 | Frame Shift Del (DEL) | VAF 58/155 reads (37%) | called by mutect2, varscan2
- DESI2 | c.320del p.N107Tfs*116 | Frame Shift Del (DEL) | VAF 54/188 reads (29%) | called by mutect2, pindel, varscan2
- DEUP1 | c.29+1dup | Frame Shift Ins (INS) | VAF 77/322 reads (24%) | called by mutect2, pindel, varscan2
- DIS3L2 | c.1835del p.P612Rfs*33 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- DUSP14 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFHC2 | c.1955del p.N652Mfs*19 | Frame Shift Del (DEL) | VAF 70/422 reads (17%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- EIF4H | c.537del p.M180Wfs*46 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, varscan2
- ESRP1 | c.1535dup p.N512Kfs*8 | Frame Shift Ins (INS) | VAF 40/136 reads (29%) | called by mutect2, varscan2
- ETV5 | c.1277_1278del p.L426Pfs*5 | Frame Shift Del (DEL) | VAF 49/212 reads (23%) | called by pindel, varscan2
- FES | c.1600del p.Q534Sfs*23 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- FGF21 | c.212del p.G71Afs*13 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- FLT3LG | c.669del p.V224Sfs*41 (on ENST00000594009 / NM_001204503.2; = p.V224Sfs*24 on NM_001459.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- FOXN2 | c.321del p.K107Nfs*60 | Frame Shift Del (DEL) | VAF 82/284 reads (29%) | called by mutect2, varscan2
- FOXO1 | c.1550_1552del p.M517del | In Frame Del (DEL) | VAF 40/153 reads (26%) | called by pindel, varscan2
- FOXP4 | c.798del p.K267Rfs*100 (on ENST00000307972 / NM_001012426.1; = p.K266Rfs*100 on NM_138457.3) | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2
- FRAS1 | c.5574del p.F1858Lfs*17 | Frame Shift Del (DEL) | VAF 84/317 reads (26%) | called by mutect2, pindel, varscan2
- FRRS1 | c.370dup p.T124Nfs*4 | Frame Shift Ins (INS) | VAF 87/299 reads (29%) | called by mutect2, varscan2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 114/336 reads (34%) | called by mutect2, varscan2
- GPR179 | c.1831C>T p.L611F (on ENST00000621958; = p.L610F on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/208 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- GTF2F1 | c.887_889del p.E296del | In Frame Del (DEL) | VAF 20/67 reads (30%) | called by pindel, varscan2
- H1-3 | c.555del p.A186Lfs*? | Frame Shift Del (DEL) | VAF 27/193 reads (14%) | called by mutect2, varscan2
- HECTD4 | c.2274del p.D759Ifs*19 | Frame Shift Del (DEL) | VAF 84/298 reads (28%) | called by mutect2, pindel, varscan2
- HTR5A | c.1006del p.L336* | Frame Shift Del (DEL) | VAF 34/372 reads (9%) | called by mutect2, pindel
- IGLV3-10 | c.147del p.K49Nfs*43 | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | called by mutect2, pindel, varscan2
- IL6ST | c.1626dup p.P543Sfs*3 | Frame Shift Ins (INS) | VAF 37/140 reads (26%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 124/196 reads (63%) | called by mutect2, varscan2
- KIAA1109 | c.2584del p.L862* | Frame Shift Del (DEL) | VAF 81/305 reads (27%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.1142del p.K381Rfs*17 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- LAMB4 | c.4426_4428del p.E1476del | In Frame Del (DEL) | VAF 127/415 reads (31%) | called by pindel, varscan2
- LRP2 | c.11898dup p.E3967Rfs*6 | Frame Shift Ins (INS) | VAF 87/337 reads (26%) | called by mutect2, pindel, varscan2
- MAN2A1 | c.994del p.W332Gfs*17 | Frame Shift Del (DEL) | VAF 39/161 reads (24%) | called by mutect2, pindel, varscan2
- MED13L | c.2966dup p.A990Cfs*6 | Frame Shift Ins (INS) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- METTL2B | c.941_942del p.Y314Cfs*4 | Frame Shift Del (DEL) | VAF 123/404 reads (30%) | called by mutect2, pindel, varscan2
- MIA2 | c.268del p.S90Vfs*19 | Frame Shift Del (DEL) | VAF 77/271 reads (28%) | called by mutect2, pindel, varscan2
- MRC2 | c.3656del p.G1219Afs*5 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- MSS51 | c.585del p.L196Yfs*3 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- MTF1 | c.1385dup p.A463Cfs*19 | Frame Shift Ins (INS) | VAF 33/135 reads (24%) | called by mutect2, pindel, varscan2
- MYH13 | c.1807del p.L603* | Frame Shift Del (DEL) | VAF 82/286 reads (29%) | called by mutect2, pindel, varscan2
- MYO9B | c.5926_5928del p.E1976del | In Frame Del (DEL) | VAF 22/92 reads (24%) | called by pindel, varscan2
- NCOA5 | c.269_270del p.F90Sfs*2 | Frame Shift Del (DEL) | VAF 42/153 reads (27%) | called by mutect2, pindel, varscan2
- NDST3 | c.2238del p.W747Gfs*19 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | called by mutect2, varscan2
- OMP | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- PHF1 | c.1446dup p.T483Hfs*5 (on ENST00000374516 / NM_024165.3; = p.Q448Tfs*86 on NM_002636.5) | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- PLCG1 | c.693del p.F232Sfs*7 | Frame Shift Del (DEL) | VAF 64/203 reads (32%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.766del p.Q256Rfs*6 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- PNISR | c.407del p.P136Lfs*26 | Frame Shift Del (DEL) | VAF 85/303 reads (28%) | called by mutect2, pindel, varscan2
- POLR3G | c.*6dup | Frame Shift Ins (INS) | VAF 48/170 reads (28%) | called by mutect2, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 68/257 reads (26%) | called by mutect2, pindel, varscan2
- PRICKLE1 | c.766dup p.E256Gfs*13 | Frame Shift Ins (INS) | VAF 39/124 reads (31%) | called by mutect2, pindel, varscan2
- PRKCH | c.1842del p.F614Lfs*9 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- PRPF4B | c.2340del p.K780Nfs*13 | Frame Shift Del (DEL) | VAF 107/362 reads (30%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 95/341 reads (28%) | called by mutect2, pindel, varscan2
- RXFP2 | c.1689dup p.G564Wfs*16 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- SCAF11 | c.2558del p.K853Rfs*46 | Frame Shift Del (DEL) | VAF 69/236 reads (29%) | called by mutect2, pindel, varscan2
- SCAPER | c.268del p.T90Qfs*9 | Frame Shift Del (DEL) | VAF 149/469 reads (32%) | called by mutect2, pindel, varscan2
- SEC61B | c.162del p.M55Cfs*22 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- SESN2 | c.685del p.Q229Rfs*18 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- SGO2 | c.2663del p.K888Sfs*16 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- SLC10A1 | c.859del p.L287Sfs*4 | Frame Shift Del (DEL) | VAF 62/200 reads (31%) | called by mutect2, pindel, varscan2
- SLC17A2 | c.987_989del p.G330del | In Frame Del (DEL) | VAF 21/91 reads (23%) | called by pindel, varscan2
- SLC38A8 | c.500dup p.R168Afs*38 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2548del p.V850* | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | called by mutect2, pindel, varscan2
- SUN5 | c.879del p.K294Rfs*47 | Frame Shift Del (DEL) | VAF 66/233 reads (28%) | called by mutect2, pindel, varscan2
- SUV39H1 | c.592del p.A198Rfs*140 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- TENM3 | c.5753del p.P1918Rfs*60 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- TLE1 | c.1389del p.D464Tfs*27 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | called by mutect2, pindel, varscan2
- TMC4 | c.166del p.V56Cfs*94 (on ENST00000617472 / NM_001145303.3; = p.V50Cfs*94 on NM_144686.4) | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- TOPBP1 | c.3798del p.K1266Nfs*10 | Frame Shift Del (DEL) | VAF 85/317 reads (27%) | called by mutect2, pindel, varscan2
- TTC14 | c.213del p.A72Rfs*33 | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2529del p.F843Lfs*34 | Frame Shift Del (DEL) | VAF 106/456 reads (23%) | called by mutect2, pindel, varscan2
- UHRF1BP1 | c.858dup p.S287Qfs*29 | Frame Shift Ins (INS) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- UIMC1 | c.508_509del p.I170Qfs*7 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | called by pindel, varscan2
- WWC2 | c.616del p.M206Cfs*17 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | called by mutect2, pindel, varscan2
- YTHDC2 | c.2530del p.M844Wfs*8 | Frame Shift Del (DEL) | VAF 93/342 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB7C | c.960del p.P321Lfs*18 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- ZEB1 | c.1880del p.K627Sfs*26 | Frame Shift Del (DEL) | VAF 45/146 reads (31%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 68/214 reads (32%) | called by mutect2, varscan2
- ZNF2 | c.588del p.F196Lfs*38 (on ENST00000611147 / NM_001291605.2; = p.F183Lfs*38 on NM_021088.4) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- ZWILCH | c.954del p.D319Tfs*7 | Frame Shift Del (DEL) | VAF 63/217 reads (29%) | called by mutect2, pindel, varscan2
- ABCA2 | c.3222A>G p.P1074= (on ENST00000614293; = p.P1044= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55797287; called by muse, mutect2, varscan2
- ABL2 | c.3162G>A p.S1054= (on ENST00000502732 / NM_007314.4; = p.S1039= on NM_005158.5) | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs148651616; called by muse, mutect2, varscan2
- ACADL | c.90C>T p.S30= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as rs755556107, COSV52052109, COSV99285131; called by muse, mutect2, varscan2
- ACO1 | c.2148C>T p.D716= | Silent (SNP) | VAF 79/238 reads (33%) | catalogued as rs777247934, COSV59376605; called by muse, mutect2, varscan2
- ADAMTS18 | c.1923C>T p.N641= | Silent (SNP) | VAF 67/219 reads (31%) | catalogued as COSV51398616; called by muse, mutect2, varscan2
- AK4 | c.492C>T p.P164= | Silent (SNP) | VAF 93/301 reads (31%) | catalogued as rs750189239, COSV100519865, COSV59196282; called by muse, mutect2, varscan2
- ALMS1 | c.6988A>C p.R2330= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV52502471, COSV52524293; called by muse, mutect2, varscan2
- AMIGO3 | c.285C>T p.N95= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57537462; called by muse, mutect2, varscan2
- ANGEL1 | c.1155G>A p.P385= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs767762469, COSV51871816; called by muse, mutect2, varscan2
- ANK1 | c.1479C>T p.N493= | Silent (SNP) | VAF 66/190 reads (35%) | catalogued as rs759412984, COSV55872595; called by muse, mutect2, varscan2
- ANKRD27 | c.3081G>A p.A1027= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs140577382; called by mutect2, varscan2
200 further variants in this file (0 protein-altering or splice-affecting, 183 silent, 17 other) are not listed here.
